Somatic mutation profile of tumor specimen TCGA-2G-AAF8-01A (aliquot TCGA-2G-AAF8-01A-11D-A42Y-10) from TCGA case TCGA-2G-AAF8, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 33.6 years (12,256 days).
Specimen TCGA-2G-AAF8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e4be72aa-4121-4459-84c7-f3c60d7cbf6f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAF8-10A (Blood Derived Normal), aliquot TCGA-2G-AAF8-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5094058f-16dd-480e-a05b-c859120400a1

The open-access MAF lists 16 somatic variants for this specimen: 7 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 7, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CAMSAP1 | c.1070G>T p.S357I | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.218); catalogued as COSV100409658; called by muse, mutect2, varscan2
- CLCNKA | c.1873G>T p.G625C | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- CSRNP3 | c.551C>A p.A184D | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GTF2E1 | c.114C>G p.I38M | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- KCNV1 | c.258C>A p.S86R | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.604); called by muse, mutect2
- RNF31 | c.1684C>T p.H562Y | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- SP6 | c.22T>G p.S8A | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- ADAM2 | c.27C>T p.S9= | Silent (SNP) | VAF 24/111 reads (22%) | catalogued as rs770804618, COSV55865571; called by muse, mutect2, varscan2
- CASP8 | c.456G>A p.L152= (on ENST00000432109 / NM_033355.3; = p.L184= on NM_001228.4) | Silent (SNP) | VAF 12/75 reads (16%) | called by muse, mutect2, varscan2
- HES1 | c.39G>A p.P13= | Silent (SNP) | VAF 14/188 reads (7%) | catalogued as rs1274230672; called by muse, mutect2
- PRR19 | c.480C>G p.A160= | Silent (SNP) | VAF 5/37 reads (14%) | called by muse, mutect2, varscan2
- PTDSS2 | c.1314G>A p.L438= | Silent (SNP) | VAF 19/103 reads (18%) | called by muse, mutect2, varscan2
- TAF1B | c.1317C>T p.D439= | Silent (SNP) | VAF 9/79 reads (11%) | called by muse, mutect2, varscan2
- TNPO2 | c.1719C>G p.L573= | Silent (SNP) | VAF 7/78 reads (9%) | called by muse, mutect2
- EEF1E1 | c.384+30T>A | Intron (SNP) | VAF 20/106 reads (19%) | called by muse, mutect2, varscan2
- TSGA10 | c.*29G>C | 3'UTR (SNP) | VAF 41/221 reads (19%) | called by muse, mutect2, varscan2
